Somatic mutation profile of tumor specimen TCGA-DX-AB2P-01A (aliquot TCGA-DX-AB2P-01A-11D-A387-09) from TCGA case TCGA-DX-AB2P, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 79.8 years (29,136 days).
Specimen TCGA-DX-AB2P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bffc7df-c167-4b5f-aa1a-b2855c104023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2P-10A (Blood Derived Normal), aliquot TCGA-DX-AB2P-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7653c7d-4c05-4fff-b062-1e0d2c461997

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A3 | c.4265A>G p.D1422G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99318701; called by muse, mutect2, varscan2
- CRB1 | c.2733T>A p.C911* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100957832; called by muse, mutect2, varscan2
- DMXL2 | c.3550A>T p.T1184S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99196265; called by muse, mutect2, varscan2
- DNAH9 | c.8071T>G p.F2691V | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1041695768, COSV99305469; called by muse, mutect2
- DOT1L | c.1798-2A>T p.X600_splice | Splice Site (SNP) | VAF 11/125 reads (9%) | catalogued as COSV101288628; called by muse, mutect2
- DROSHA | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs753623166, COSV60783548; called by muse, mutect2, varscan2
- FAM47C | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 99/116 reads (85%) | catalogued as COSV100792471, COSV63729196; called by muse, mutect2, varscan2
- FPR1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100494042; called by muse, mutect2
- GRIK3 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1273819035, COSV66135581; called by muse, mutect2, varscan2
- HERC2 | c.7633G>T p.V2545L | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.956); catalogued as COSV99873011; called by muse, mutect2
- KALRN | c.3211C>T p.R1071W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99563721; called by muse, mutect2, varscan2
- NPTX2 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as COSV55718328, COSV99674848; called by muse, mutect2, varscan2
- OR6A2 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV60264361; called by muse, mutect2
- PIK3C2B | c.2688C>A p.D896E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100916085; called by muse, mutect2
- PTPRC | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100722528, COSV61405783; called by muse, mutect2, varscan2
- SMAD4 | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61693160; called by muse, mutect2
- SRBD1 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99765556; called by muse, mutect2
- TCERG1 | c.3152T>G p.L1051* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99694718; called by muse, mutect2
- UGGT2 | c.3718C>G p.H1240D | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948641; called by muse, varscan2
- VPS13D | c.7882G>A p.E2628K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as COSV50652035, COSV99166267; called by muse, mutect2, varscan2
- WARS1 | c.282T>G p.S94R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100690141; called by muse, mutect2, varscan2
- ZNF695 | c.1136C>A p.P379Q | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100377404; called by muse, mutect2, varscan2
- ATRX | c.351dup p.M118Yfs*19 | Frame Shift Ins (INS) | VAF 24/40 reads (60%) | called by mutect2, pindel, varscan2
- KMT2A | c.3908_3914del p.L1303Pfs*51 | Frame Shift Del (DEL) | VAF 23/36 reads (64%) | called by mutect2, pindel, varscan2
- TLL2 | c.184del p.W62Gfs*6 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- UNC13A | c.2366C>A p.T789N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2
- ADAD2 | c.1623C>T p.A541= (on ENST00000315906 / NM_001145400.2; = p.A623= on NM_139174.4) | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as COSV99235263, COSV99235322; called by muse, mutect2, varscan2
- FUT10 | c.1077C>A p.I359= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100161371; called by muse, mutect2
- HEATR5A | c.3093C>T p.S1031= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV101119907; called by muse, mutect2, varscan2
- MYO18B | c.4392G>A p.R1464= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100123419; called by muse, mutect2, varscan2
- NNT | c.3051A>G p.Q1017= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV99238804; called by muse, mutect2, varscan2
- OR6C3 | c.456C>A p.T152= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101110348; called by muse, mutect2, varscan2
- PITPNM1 | c.2355G>A p.E785= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV54160820, COSV99653649; called by muse, mutect2, varscan2
- SLC9A5 | c.2397G>A p.E799= | Silent (SNP) | VAF 58/68 reads (85%) | catalogued as COSV100237250; called by muse, mutect2, varscan2
- TRPM6 | c.1354C>A p.R452= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV100666233, COSV62503162; called by muse, mutect2, varscan2
- RUSC1 | c.-87+43G>C | Intron (SNP) | VAF 18/31 reads (58%) | catalogued as COSV99429716; called by muse, mutect2, varscan2
